FM case AD3702 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Paragangliomas and Glomus Tumors.
https://portal.gdc.cancer.gov/cases/f7c63f70-458b-4bab-aff2-3266d124b68a

Male, 60.4 years: Paraganglioma, NOS (ICD-O-3 8680/1); metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
